Somatic mutation profile of tumor specimen 0DVCFE from CCDI case PBCLRG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Mandible; Age at diagnosis: 7.4 years (2,696 days).
Specimen 0DVCFE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c027d9-39f8-4d03-85f4-917e08fd082f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e60cdadd-293a-483f-b244-cd7fbe659744

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Silent 3, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCLK1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 70/1012 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55171630; called by muse, mutect2
- FCHSD1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 107/826 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs376436093; called by muse, mutect2, varscan2
- KMT2A | c.9893C>T p.P3298L | Missense Mutation (SNP) | VAF 43/614 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.066); catalogued as rs781852468, COSV63289383; called by muse, mutect2
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs1554342786; called by mutect2, varscan2
- SIVA1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 69/602 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766681672; called by muse, mutect2, varscan2
- AMN1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 47/884 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- NAV2 | c.7114G>A p.E2372K (on ENST00000396087 / NM_001244963.2; = p.E2313K on NM_145117.5) | Missense Mutation (SNP) | VAF 129/1076 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 36/377 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.19); called by mutect2, varscan2
- SPTA1 | c.4737+1G>A p.X1579_splice | Splice Site (SNP) | VAF 93/1403 reads (7%) | called by muse, mutect2
- DCHS2 | c.756G>C p.R252= | Silent (SNP) | VAF 26/457 reads (6%) | called by muse, mutect2
- MYO5B | c.222G>A p.L74= | Silent (SNP) | VAF 76/1352 reads (6%) | called by muse, mutect2
- TOX | c.537G>A p.L179= | Silent (SNP) | VAF 35/723 reads (5%) | called by muse, mutect2
- ABCB7 | c.1832-10C>A | Intron (SNP) | VAF 44/686 reads (6%) | called by muse, mutect2
- FLT4 | c.2168-47C>T | Intron (SNP) | VAF 38/481 reads (8%) | catalogued as rs778740732, COSV56110206; called by muse, mutect2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 22/245 reads (9%) | catalogued as rs1415560984; called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 30/186 reads (16%) | called by muse, varscan2
